Gene-level copy-number profile of tumor specimen TCGA-VQ-A91K-01A from TCGA case TCGA-VQ-A91K, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 69.6 years (25,424 days).
Specimen TCGA-VQ-A91K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3468c43b-5493-4717-b780-d485c7f7c872.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa90eee2-43e5-4625-9a7f-9e537d637db4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 3,875; copy number 3: 52; copy number 4: 55,102; copy number 5: 3; copy number 6: 713; copy number 7: 31; copy number 8: 8; copy number 9: 30; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91K-01A-11D-A40Z-01): tumor purity 0.72, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 31 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–206,392, 4 genes, copy number 9: AL035696.2, AL035696.3, AL035696.4, AL035696.1.
- chr6:6,169,304–6,169,435, 2 genes, copy number 9: MIR7853, MIR5683.
- chr6:25,181,359–25,181,745, 1 gene, copy number 10: AL590084.1.
- chr19:4,304,598–4,622,307, 24 genes, copy number 9: FSD1, STAP2, AC104521.1, MPND, AC007292.3, EIF1P6, AC007292.2, SH3GL1, AC007292.1, CHAF1A, AC011498.3, UBXN6, MIR4746, AC011498.2, AC011498.7, AC011498.6, AC011498.1, HDGFL2, PLIN4, PLIN5, AC011498.4, LRG1, SEMA6B, AC011498.5.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
